Somatic mutation profile of tumor specimen TCGA-BP-5199-01A (aliquot TCGA-BP-5199-01A-01D-1429-08) from TCGA case TCGA-BP-5199, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 58.2 years (21,256 days).
Specimen TCGA-BP-5199-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7843bc6-b296-409e-89ea-d6f9e7fd7064.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5199-11A (Solid Tissue Normal), aliquot TCGA-BP-5199-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/068cee59-9afc-4271-9add-aadbfc75b2cd

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Frame Shift Del 8, Splice Site 4, Frame Shift Ins 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.613_617del p.L205Kfs*4 | Frame Shift Del (DEL) | VAF 61/237 reads (26%) | catalogued as rs1060503441; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM10 | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as COSV53055274; called by muse, mutect2, varscan2
- ALPK3 | c.4205T>C p.L1402P | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51932385; called by muse, mutect2, varscan2
- ARID1A | c.6072del p.K2025Sfs*5 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as COSV61371968; called by pindel, varscan2
- ASPM | c.3847A>G p.K1283E | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV54139851; called by muse, mutect2
- ASPM | c.3845T>C p.L1282P | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs886045776, COSV54139861; ClinVar: uncertain significance; called by muse, mutect2
- BICRA | c.2922C>A p.N974K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV67606671; called by muse, mutect2, varscan2
- CACNA1S | c.3304A>C p.I1102L | Missense Mutation (SNP) | VAF 147/525 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62944316; called by muse, mutect2, varscan2
- CLCN6 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56743485; called by muse, mutect2, varscan2
- CLCN6 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs749795306, COSV56743501; called by mutect2, varscan2
- COL4A6 | c.66+1G>T p.X22_splice | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57879938; called by muse, mutect2, varscan2
- COQ10A | c.520T>C p.W174R | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57526059; called by muse, mutect2, varscan2
- CYB5R3 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61546805; called by muse, mutect2, varscan2
- FAT2 | c.10486T>C p.W3496R | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55830771; called by muse, mutect2, varscan2
- FOXRED1 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV55005067, COSV55009245; called by muse, mutect2, varscan2
- FOXRED1 | c.348T>A p.C116* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as COSV55009265; called by muse, mutect2, varscan2
- FTO | c.768T>G p.S256R | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV67114604; called by muse, mutect2, varscan2
- GALNT17 | c.930G>T p.W310C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61194620; called by muse, varscan2
- GBF1 | c.1507C>G p.L503V (on ENST00000369983 / NM_001377137.1; = p.L502V on NM_004193.3) | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV64149502; called by muse, mutect2, varscan2
- GIMAP6 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61035009; called by muse, mutect2, varscan2
- GPR183 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs141594545; called by muse, mutect2
- HAP1 | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.422); catalogued as COSV57881041; called by muse, mutect2, varscan2
- HMCN1 | c.14177G>T p.G4726V | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54945702; called by muse, mutect2, varscan2
- KLHL4 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV64147357; called by muse, mutect2, varscan2
- KRT75 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs148964521; called by muse, mutect2, varscan2
- MAP3K6 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.917); catalogued as COSV54642955; called by muse, mutect2, varscan2
- MGAT5 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56101634; called by muse, mutect2, varscan2
- MICU1 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV63148181; called by muse, mutect2, varscan2
- MYH4 | c.348+1G>A p.X116_splice | Splice Site (SNP) | VAF 33/187 reads (18%) | catalogued as rs961801438, COSV55127327, COSV99701229; called by muse, mutect2, varscan2
- PLEKHG4 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58575607; called by muse, mutect2, varscan2
- PSMC5 | c.680-2A>G p.X227_splice | Splice Site (SNP) | VAF 39/133 reads (29%) | catalogued as COSV56742402; called by muse, mutect2, varscan2
- PTEN | c.828T>G p.N276K | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64299696, COSV64304659; called by muse, varscan2
- PYCARD | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56008746; called by muse, mutect2, varscan2
- RILP | c.1150T>A p.C384S | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.264); catalogued as rs556577180, COSV53961695; called by muse, mutect2, varscan2
- RPL30 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV54636796; called by muse, mutect2, varscan2
- SHH | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV51920516; called by muse, mutect2, varscan2
- SKA3 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV53437372; called by muse, mutect2, varscan2
- SLC22A12 | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.428); catalogued as COSV60574319; called by muse, mutect2, varscan2
- SLC34A3 | c.86-2A>T p.X29_splice | Splice Site (SNP) | VAF 85/366 reads (23%) | catalogued as COSV63188167; called by muse, mutect2, varscan2
- SLC39A6 | c.402T>G p.H134Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV52371666; called by muse, mutect2
- SLC66A3 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs546479821, COSV54468753; called by muse, mutect2, varscan2
- SMS | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65115483; called by muse, mutect2, varscan2
- SRRM2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57070892; called by muse, mutect2, varscan2
- SSBP4 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV54212675; called by muse, mutect2, varscan2
- STAB2 | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147807697, COSV66335384; called by muse, mutect2, varscan2
- TBXAS1 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54955230; called by muse, mutect2, varscan2
- TCEAL4 | c.93A>T p.E31D | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.301); catalogued as COSV65464171; called by muse, mutect2, varscan2
- TOM1L1 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs1235513046, COSV61949745; called by muse, mutect2, varscan2
- TRIP13 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 150/386 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51320696, COSV51322501; called by muse, varscan2
- UBN1 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs997974104, COSV52173560; called by muse, mutect2, varscan2
- VWA3B | c.3260C>A p.A1087D | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101289441, COSV69034121, COSV69034268; called by muse, mutect2, varscan2
- WNK1 | c.3899C>G p.S1300C (on ENST00000315939 / NM_018979.4; = p.S1053C on NM_014823.3) | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60046655; called by muse, mutect2, varscan2
- ZEB1 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.212); catalogued as COSV58054909; called by muse, mutect2, varscan2
- ZFP91 | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV60162313; called by muse, mutect2, varscan2
- ZNF3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV104392404, COSV52796643; called by muse, mutect2, varscan2
- ZNF513 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52011087; called by muse, mutect2, varscan2
- ZNF653 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV53405006; called by muse, mutect2, varscan2
- ZNF780A | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.435); catalogued as COSV61816900; called by muse, mutect2, varscan2
- FOXA2 | c.182del p.G61Afs*3 (on ENST00000377115 / NM_153675.3; = p.G67Afs*3 on NM_021784.5) | Frame Shift Del (DEL) | VAF 25/116 reads (22%) | called by mutect2, pindel
- GOLGA5 | c.1914_1918del p.I639Yfs*5 | Frame Shift Del (DEL) | VAF 65/253 reads (26%) | called by mutect2, pindel, varscan2
- LCAT | c.1013_1026del p.L338Pfs*24 | Frame Shift Del (DEL) | VAF 41/203 reads (20%) | called by mutect2, pindel, varscan2
- MSL3 | c.826_829dup p.Y277Sfs*3 (on ENST00000312196 / NM_078629.4; = p.Y111Sfs*3 on NM_006800.4) | Frame Shift Ins (INS) | VAF 111/186 reads (60%) | called by mutect2, pindel, varscan2
- NBPF11 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 143/579 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- PPP2R1B | c.1080_1081del p.I361Yfs*14 | Frame Shift Del (DEL) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.634dup p.Y212Lfs*11 | Frame Shift Ins (INS) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- ZNF280C | c.1466del p.K489Rfs*8 | Frame Shift Del (DEL) | VAF 31/166 reads (19%) | called by mutect2, pindel, varscan2
- ZNF609 | c.2225_2228del p.E742Vfs*3 | Frame Shift Del (DEL) | VAF 86/290 reads (30%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.1281T>C p.D427= | Silent (SNP) | VAF 60/179 reads (34%) | catalogued as COSV66361308; called by muse, mutect2, varscan2
- CEMIP2 | c.3750G>A p.V1250= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV65489871; called by muse, mutect2, varscan2
- CLEC11A | c.951C>T p.Y317= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs571444123, COSV51574192; called by muse, mutect2, varscan2
- DNAJB4 | c.894G>A p.L298= | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as rs757112735, COSV66132161; called by muse, mutect2, varscan2
- EIF2AK4 | c.2172C>A p.P724= | Silent (SNP) | VAF 50/180 reads (28%) | catalogued as COSV55474662; called by muse, mutect2, varscan2
- GPR12 | c.963G>A p.P321= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV67344973; called by muse, mutect2, varscan2
- KLHL20 | c.297A>T p.G99= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV52945417; called by muse, mutect2, varscan2
- MAK | c.726T>A p.V242= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV57568064; called by muse, mutect2, varscan2
- PCDHA9 | c.1281G>A p.A427= | Silent (SNP) | VAF 89/248 reads (36%) | catalogued as COSV65333493; called by muse, mutect2, varscan2
- SDK1 | c.1863G>A p.T621= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs375345968; called by muse, mutect2, varscan2
- SHOC2 | c.981A>G p.L327= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as rs1440014484, COSV54622994; ClinVar: likely benign; called by muse, mutect2, varscan2
- SQOR | c.417A>G p.R139= | Silent (SNP) | VAF 111/414 reads (27%) | catalogued as COSV52943766; called by muse, mutect2, varscan2
- TSHZ2 | c.1761G>T p.L587= | Silent (SNP) | VAF 14/288 reads (5%) | catalogued as COSV61591979; called by muse, mutect2
- ZGRF1 | c.3102T>C p.D1034= | Silent (SNP) | VAF 74/225 reads (33%) | catalogued as COSV58411602; called by muse, mutect2, varscan2
- ZNF276 | c.549G>A p.A183= (on ENST00000443381 / NM_001113525.2; = p.A108= on NM_152287.4) | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs767224098, COSV57073730; called by muse, mutect2, varscan2
- ZNF318 | c.5892G>A p.K1964= | Silent (SNP) | VAF 117/339 reads (35%) | catalogued as COSV58938209; called by muse, mutect2, varscan2
- ZNF687 | c.3447C>A p.S1149= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV55022098; called by muse, mutect2, varscan2
- FBH1 | c.1+4766G>T | Intron (SNP) | VAF 43/134 reads (32%) | catalogued as COSV62984689; called by muse, mutect2, varscan2
- PRR12 | c.51+196del | Intron (DEL) | VAF 6/34 reads (18%) | catalogued as COSV55871957; called by pindel, varscan2*
